Somatic mutation profile of tumor specimen TARGET-30-PASMNT-01A (aliquot TARGET-30-PASMNT-01A-01D) from TARGET case TARGET-30-PASMNT, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 13.1 years (4,802 days).
Specimen TARGET-30-PASMNT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ffd2ad8-edda-4646-84e8-9a2f52a33158.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASMNT-10A (Blood Derived Normal), aliquot TARGET-30-PASMNT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7eaf2a2e-567d-40fe-89de-de36a3e48fe4

The open-access MAF lists 41 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 7, Nonsense Mutation 3, Intron 3, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA9 | c.1744C>A p.L582M | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV60626832; called by muse, mutect2, varscan2
- ADTRP | c.499A>C p.I167L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV57644230; called by muse, mutect2, varscan2
- AHNAK | c.9990G>T p.K3330N | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV57217864; called by muse, mutect2, varscan2
- CYP4F22 | c.756C>A p.D252E | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV54109521; called by muse, mutect2, varscan2
- DOCK2 | c.3781C>A p.Q1261K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.637); catalogued as COSV56966155; called by muse, mutect2, varscan2
- FAP | c.86C>A p.S29* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as COSV51863571; called by muse, mutect2, varscan2
- HELB | c.1694T>C p.F565S | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV56074330; called by muse, mutect2, varscan2
- ITGA10 | c.1522G>T p.A508S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as COSV65197951; called by muse, mutect2, varscan2
- KRTAP10-4 | c.120del p.C41Afs*13 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs781884268; called by mutect2, pindel, varscan2
- L1CAM | c.1298A>T p.N433I | Missense Mutation (SNP) | VAF 43/47 reads (91%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV62828683; called by muse, mutect2, varscan2
- MUC16 | c.29276C>T p.S9759L | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs868342937, COSV67475605; called by muse, mutect2, varscan2
- MYH9 | c.2229G>A p.M743I | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.439); catalogued as COSV53388402, COSV99337845; called by muse, mutect2, varscan2
- NCF1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs149204001, COSV56876580; called by muse, mutect2, varscan2
- NEK5 | c.154G>C p.V52L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62880557; called by muse, mutect2, varscan2
- NPFFR2 | c.1405G>T p.A469S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV100440555, COSV58151115; called by muse, mutect2, varscan2
- NRP2 | c.2414C>A p.S805* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV55930540; called by muse, mutect2, varscan2
- OR5J2 | c.573C>A p.D191E | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV56622036; called by muse, mutect2, varscan2
- PCCB | c.736G>T p.G246C | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52445988; called by muse, mutect2, varscan2
- PDS5B | c.4211A>G p.N1404S | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.115); catalogued as COSV59729305; called by muse, mutect2, varscan2
- PNMA5 | c.430T>G p.S144A | Missense Mutation (SNP) | VAF 113/116 reads (97%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100721597, COSV62625775; called by muse, mutect2, varscan2
- PSD3 | c.2353G>A p.A785T (on ENST00000440756; = p.A784T on NM_015310.4) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV54074055; called by muse, mutect2, varscan2
- RASA3 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61868759; called by muse, mutect2, varscan2
- SLC6A19 | c.495G>T p.E165D | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV58672190; called by muse, mutect2, varscan2
- SLC7A8 | c.982G>T p.G328* | Nonsense Mutation (SNP) | VAF 36/93 reads (39%) | catalogued as COSV57554705; called by muse, mutect2, varscan2
- SPRR1A | c.242C>A p.P81Q | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV61081295; called by muse, mutect2, varscan2
- SYNE1 | c.20651T>C p.I6884T (on ENST00000367255 / NM_182961.4; = p.I6813T on NM_033071.3) | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV55017706; called by muse, mutect2, varscan2
- TBX21 | c.791A>G p.H264R | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303543856, COSV51596783; called by muse, mutect2, varscan2
- TUBA3C | c.1127G>T p.C376F | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV68028779; called by muse, mutect2, varscan2
- WRNIP1 | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867029038, COSV66356158; called by muse, mutect2, varscan2
- ZNF318 | c.4932G>T p.K1644N | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV58933943; called by muse, mutect2, varscan2
- ZBTB26 | c.1089dup p.A364Cfs*3 | Frame Shift Ins (INS) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- ALAS2 | c.45C>T p.A15= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV58191544; called by muse, mutect2
- DNAH5 | c.10002C>A p.V3334= | Silent (SNP) | VAF 9/169 reads (5%) | catalogued as COSV54247153; called by muse, mutect2
- MGAT3 | c.612G>T p.V204= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV57866274; called by muse, mutect2, varscan2
- MROH2B | c.3492T>A p.T1164= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV68185832; called by muse, mutect2, varscan2
- SI | c.3543T>G p.P1181= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV52285171; called by muse, mutect2, varscan2
- SLC4A1AP | c.2364C>A p.T788= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as rs751512515, COSV58135560; called by muse, mutect2, varscan2
- TRUB2 | c.439C>T p.L147= | Silent (SNP) | VAF 61/109 reads (56%) | catalogued as COSV65759845; called by muse, mutect2, varscan2
- HIF3A | c.878-37C>A | Intron (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- TPM2 | c.563+176C>A | Intron (SNP) | VAF 27/29 reads (93%) | catalogued as COSV61406583; called by muse, mutect2, varscan2
- TTN | c.10360+4257G>T | Intron (SNP) | VAF 34/65 reads (52%) | catalogued as COSV60150051; called by muse, mutect2, varscan2
